Somatic mutation profile of tumor specimen TCGA-D8-A1JC-01A (aliquot TCGA-D8-A1JC-01A-11D-A13L-09) from TCGA case TCGA-D8-A1JC, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60.0 years (21,898 days).
Specimen TCGA-D8-A1JC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a86e946f-8190-42c1-9137-eae6411c5d61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1JC-10A (Blood Derived Normal), aliquot TCGA-D8-A1JC-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae14cea0-47b8-401f-8143-c1adb6549921

The open-access MAF lists 98 somatic variants for this specimen: 75 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 22, Frame Shift Del 6, Nonsense Mutation 4, Intron 1, Splice Site 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CB | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 29/94 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV56683948; called by muse, mutect2, varscan2
- TGM1 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918725, CM014106, CM123549, COSV52863197; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABTB2 | c.1398-1G>A p.X466_splice | Splice Site (SNP) | VAF 16/22 reads (73%) | catalogued as COSV54388602; called by muse, mutect2, varscan2
- ADAMTS20 | c.3460G>A p.A1154T | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs755614729, COSV67131830; called by muse, mutect2, varscan2
- AXIN2 | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61057685; called by muse, mutect2, varscan2
- C1orf198 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs749135657, COSV64175387; called by muse, mutect2, varscan2
- CAMK2A | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.413); catalogued as COSV62246454; called by muse, mutect2, varscan2
- CAMSAP3 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as COSV50335015; called by muse, mutect2, varscan2
- CATSPER2 | c.71A>T p.D24V | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV58660869; called by muse, mutect2, varscan2
- CCDC170 | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.587); catalogued as COSV99498055; called by muse, mutect2, varscan2
- CD19 | c.1209_1212del p.E404Kfs*64 | Frame Shift Del (DEL) | VAF 22/48 reads (46%) | catalogued as COSV61188602; called by mutect2, pindel, varscan2
- CD300LG | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV53223879; called by muse, mutect2, varscan2
- CNDP1 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 67/114 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100722153; called by muse, mutect2
- CNTN6 | c.1621G>A p.V541I | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV63172682; called by muse, mutect2, varscan2
- DNAH3 | c.8683G>A p.D2895N | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs778396681, COSV54523191; called by muse, mutect2, varscan2
- DNAJB1 | c.514C>A p.L172I | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99583968; called by muse, mutect2, varscan2
- EPOR | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV55799627; called by muse, mutect2, varscan2
- ERCC4 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs373570729; called by muse, mutect2, varscan2
- EYA4 | c.662G>A p.S221N | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs869025402, COSV62052426; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F8 | c.6382G>T p.G2128W | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64273729; called by muse, mutect2, varscan2
- FAM81B | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as rs1561297981, COSV51983174; called by muse, mutect2, varscan2
- FCGBP | c.6824C>T p.P2275L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1452040648; called by muse, mutect2, varscan2
- FLG | c.4354G>C p.E1452Q | Missense Mutation (SNP) | VAF 21/312 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as rs1219330641, COSV100910361; called by muse, mutect2
- GABRB1 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54976712; called by muse, mutect2, varscan2
- GOPC | c.684G>A p.M228I | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV50002188; called by muse, mutect2, varscan2
- GRIN2A | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.185); catalogued as rs867464241, COSV58027342, COSV58033157; called by muse, mutect2, varscan2
- HADH | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as COSV58848219, COSV58850462; called by muse, mutect2, varscan2
- HCFC1 | c.4354G>A p.D1452N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.063); catalogued as rs782354389, COSV60072461; called by muse, mutect2, varscan2
- HEATR5B | c.426G>C p.L142F | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99248012; called by muse, mutect2
- IL18R1 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as COSV52124682; called by muse, mutect2, varscan2
- IL20 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as COSV65584567; called by muse, mutect2, varscan2
- KIAA1210 | c.5012G>A p.R1671Q | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV68177286; called by muse, mutect2, varscan2
- KIF23 | c.2186G>C p.W729S | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52979953; called by muse, mutect2, varscan2
- KIF5C | c.2500A>G p.I834V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV101276083; called by muse, mutect2
- LRP4 | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66135937; called by muse, mutect2, varscan2
- LRRIQ1 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.249); catalogued as COSV67813067, COSV67813636; called by muse, mutect2, varscan2
- MAB21L3 | c.789G>C p.M263I | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV65673899; called by muse, mutect2, varscan2
- MAD1L1 | c.1842G>C p.K614N | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99764940; called by muse, mutect2
- MMP14 | c.384C>G p.I128M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61287847, COSV61288343; called by muse, mutect2, varscan2
- MRPS25 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 40/85 reads (47%) | catalogued as rs1046101036, COSV53741444; called by muse, mutect2, varscan2
- MYH13 | c.348C>T p.Y116= | Splice Region (SNP) | VAF 98/178 reads (55%) | catalogued as rs767555564, COSV52829494; called by muse, mutect2, varscan2
- MYH8 | c.1854G>T p.K618N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV67965444; called by muse, mutect2, varscan2
- NAMPT | c.1237G>C p.V413L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55995175; called by muse, mutect2, varscan2
- NECTIN4 | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs558365881, COSV63512770, COSV63513181; called by muse, mutect2, varscan2
- NECTIN4 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100919792; called by muse, mutect2
- NIPBL | c.5272C>T p.R1758* | Nonsense Mutation (SNP) | VAF 38/136 reads (28%) | catalogued as CM042515, COSV56948411, COSV56958347; called by muse, mutect2, varscan2
- NKAIN2 | c.131T>A p.I44N | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63661615; called by muse, mutect2, varscan2
- NLGN4X | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV52018846; called by muse, mutect2, varscan2
- NLGN4Y | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV100196275; called by muse, mutect2
- PCDHB3 | c.2322C>A p.F774L | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV50566253, COSV50575056; called by muse, mutect2, varscan2
- PCLO | c.13291G>C p.D4431H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61636308; called by muse, mutect2, varscan2
- PDZD2 | c.315G>C p.K105N | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56858751; called by muse, mutect2, varscan2
- RALGAPA1 | c.1934T>A p.L645* | Nonsense Mutation (SNP) | VAF 33/94 reads (35%) | catalogued as COSV51883532; called by muse, mutect2, varscan2
- RASAL2 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs762969560, COSV62709863; called by muse, mutect2, varscan2
- RBM33 | c.3394C>G p.Q1132E | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); catalogued as COSV100355052; called by muse, mutect2
- RBM6 | c.1644C>G p.N548K | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV56483007, COSV99804796; called by muse, mutect2, varscan2
- RMND5A | c.756C>A p.H252Q | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.309); catalogued as COSV52153800; called by muse, mutect2, varscan2
- RPGR | c.1406A>T p.E469V | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100139483; called by muse, mutect2, varscan2
- SACS | c.2888C>G p.S963C | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV66540209; called by muse, mutect2, varscan2
- SLC4A3 | c.2243C>A p.A748D | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56093941; called by muse, mutect2, varscan2
- SMC4 | c.2083G>C p.D695H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748833024, COSV61004927, COSV61006431, COSV99048933; called by muse, mutect2, varscan2
- SRGAP2 | c.1993G>C p.E665Q (on ENST00000624873 / NM_001170637.4; = p.E666Q on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.342); catalogued as COSV55337742; called by muse, mutect2, varscan2
- SYN1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV99926987; called by muse, mutect2
- TBX18 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63736723, COSV63736909; called by muse, mutect2, varscan2
- TC2N | c.390C>G p.F130L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100562945, COSV61747005; called by muse, mutect2, varscan2
- TET1 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV65384903; called by muse, mutect2, varscan2
- TRIML1 | c.323A>T p.D108V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV60194365; called by muse, mutect2, varscan2
- TRMT10C | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV59305923; called by muse, mutect2, varscan2
- USF3 | c.5363G>A p.R1788H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201006777, COSV57072020; called by muse, mutect2, varscan2
- ADGRB1 | c.1621_1627del p.G541Sfs*47 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, varscan2
- DCDC1 | c.5290_5300del p.A1764Cfs*? (on ENST00000597505 / NM_001367979.1; = p.A871Cfs*45 on NM_020869.3) | Frame Shift Del (DEL) | VAF 36/115 reads (31%) | called by mutect2, pindel, varscan2
- DUS4L-BCAP29 | c.631del p.I211Yfs*3 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, varscan2
- GPR82 | c.817dup p.Y273Lfs*8 | Frame Shift Ins (INS) | VAF 13/59 reads (22%) | called by mutect2, pindel, varscan2
- SCYL1 | c.2179_2180del p.W727Gfs*30 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, varscan2
- ZNF44 | c.1117_1128delinsTA p.Q373* (on ENST00000356109 / NM_001164276.2; = p.Q325* on NM_016264.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by pindel, varscan2*
- ASTN1 | c.2937G>A p.Q979= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as rs756032018, COSV100708140, COSV62497240; called by muse, mutect2, varscan2
- C1orf226 | c.201G>A p.R67= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV63395399; called by muse, mutect2, varscan2
- CEP89 | c.1395G>A p.L465= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV99992950; called by muse, mutect2, varscan2
- CTCF | c.1689A>T p.T563= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as COSV50469536, COSV50540839; called by muse, mutect2, varscan2
- CYP11B1 | c.840C>T p.F280= | Silent (SNP) | VAF 30/157 reads (19%) | catalogued as COSV52827349; called by muse, mutect2, varscan2
- DAB2 | c.777C>T p.G259= | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as COSV57914511; called by muse, mutect2, varscan2
- E2F1 | c.915G>A p.G305= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99864399; called by muse, mutect2
- FAM227B | c.1251C>T p.L417= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV54811258; called by muse, mutect2, varscan2
- FANCG | c.1008A>G p.S336= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as COSV62720624; called by muse, mutect2, varscan2
- FBXO32 | c.390A>G p.A130= | Silent (SNP) | VAF 81/126 reads (64%) | catalogued as COSV54891130; called by muse, mutect2, varscan2
- KCNQ3 | c.702C>T p.I234= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV66471288; called by muse, mutect2, varscan2
- MPI | c.699C>T p.I233= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV60396513, COSV60396848; called by muse, mutect2, varscan2
- MRPL3 | c.798G>A p.R266= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV53914349; called by muse, mutect2, varscan2
- MVP | c.1395C>T p.N465= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs774680750, COSV62421666; called by muse, mutect2, varscan2
- MYO7A | c.2274C>T p.F758= | Silent (SNP) | VAF 22/222 reads (10%) | catalogued as COSV101289013; called by muse, mutect2
- NCR1 | c.399A>G p.E133= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV52556161, COSV52556700; called by muse, mutect2, varscan2
- PPFIA1 | c.1146G>A p.L382= | Silent (SNP) | VAF 16/168 reads (10%) | catalogued as COSV99556671; called by muse, mutect2
- PRG4 | c.3528C>T p.F1176= | Silent (SNP) | VAF 58/201 reads (29%) | catalogued as COSV63355596; called by muse, mutect2, varscan2
- RBM12B | c.1557C>T p.Y519= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as rs758479257, COSV67898031; called by muse, mutect2, varscan2
- THAP9 | c.2064C>T p.H688= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs150289561, COSV56356507; called by muse, mutect2, varscan2
- TSC2 | c.4180C>T p.L1394= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs911307922, CD000094, CD994026, COSV99236989; ClinVar: likely benign; called by muse, mutect2, varscan2
- VSIG4 | c.711C>T p.L237= | Silent (SNP) | VAF 61/139 reads (44%) | catalogued as COSV66073800; called by muse, mutect2, varscan2
- PLPP5 | c.463+48G>C | Intron (SNP) | VAF 110/307 reads (36%) | catalogued as COSV57669570; called by muse, mutect2, varscan2
